Somatic mutation profile of tumor specimen TCGA-97-8174-01A (aliquot TCGA-97-8174-01A-11D-2284-08) from TCGA case TCGA-97-8174, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.7 years (24,725 days).
Specimen TCGA-97-8174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4658d37a-466c-40c5-a8a9-3ca0996b6dc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8174-10A (Blood Derived Normal), aliquot TCGA-97-8174-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1234497-2a27-46d5-b030-d12748185c4a

The open-access MAF lists 175 somatic variants for this specimen: 137 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 37, Nonsense Mutation 11, Splice Site 5, Frame Shift Del 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101229325, COSV67960197; called by muse, mutect2, varscan2
- ADGRG4 | c.8858G>A p.W2953* | Nonsense Mutation (SNP) | VAF 63/140 reads (45%) | catalogued as COSV99794904; called by muse, mutect2, varscan2
- AFF3 | c.1898A>G p.N633S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100418361; called by muse, mutect2, varscan2
- ALPI | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs764795958, COSV55016598; called by muse, mutect2, varscan2
- ALPK1 | c.2651G>T p.R884M | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51584570; called by muse, mutect2, varscan2
- ANK2 | c.10625C>A p.S3542Y | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100000536, COSV52148657; called by muse, mutect2, varscan2
- ATG2B | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149230704, COSV55889950; called by muse, mutect2, varscan2
- ATG3 | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99344005; called by muse, mutect2, varscan2
- ATP2A2 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58042193; called by muse, mutect2, varscan2
- AZGP1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99447787; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3658G>T p.G1220* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100863678; called by muse, mutect2, varscan2
- BLK | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.629); catalogued as COSV99377001; called by muse, mutect2, varscan2
- C20orf194 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99330460; called by muse, mutect2
- CADM3 | c.676C>T p.R226C (on ENST00000368125 / NM_001127173.3; = p.R260C on NM_021189.5) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.731); catalogued as rs1057465032, COSV63683841; called by muse, mutect2
- CAMTA1 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100347642; called by muse, mutect2, varscan2
- CAMTA1 | c.4770C>G p.F1590L | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100347645; called by muse, mutect2
- CCDC181 | c.1324T>G p.L442V (on ENST00000367806 / NM_001300969.1; = p.L441V on NM_021179.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.543); catalogued as COSV100250550; called by muse, mutect2, varscan2
- CCDC68 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as COSV100491675; called by muse, mutect2, varscan2
- CDH7 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59881844; called by muse, mutect2
- CEACAM6 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | catalogued as rs1225077419, COSV99555483; called by muse, mutect2
- CECR2 | c.3970G>A p.A1324T (on ENST00000342247 / NM_001290047.2; = p.A1140T on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs897079322, COSV52849253; called by muse, mutect2
- CEP170 | c.3208G>T p.G1070* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100316722; called by muse, mutect2, varscan2
- CEP55 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV101016911; called by muse, mutect2, varscan2
- CFAP61 | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV99843984; called by muse, mutect2
- CHPF | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60535603, COSV99704792; called by muse, mutect2
- CILP2 | c.2180T>A p.F727Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV99364476; called by muse, mutect2, varscan2
- CNKSR2 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54250597, COSV54268361; called by muse, mutect2, varscan2
- CNOT11 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.276); catalogued as COSV56819866, COSV99179240; called by muse, mutect2, varscan2
- COL12A1 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100485650; called by muse, mutect2, varscan2
- COL26A1 | c.1229T>A p.M410K (on ENST00000313669 / NM_001278563.3; = p.M408K on NM_133457.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV100561583; called by muse, mutect2, varscan2
- DDR2 | c.1735C>T p.L579F | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906317; called by muse, mutect2, varscan2
- DNAH9 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV99304948; called by muse, mutect2, varscan2
- DNAJB8 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV100048187; called by muse, mutect2, varscan2
- ECHS1 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV100881886; called by muse, mutect2
- EHHADH | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV99213130; called by muse, mutect2
- EIF2AK1 | c.1405A>G p.I469V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as rs909654565, COSV99551717; called by muse, mutect2, varscan2
- ENPP3 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs371282868, COSV62953651; called by muse, mutect2, varscan2
- FANCM | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV53532315; called by muse, mutect2, varscan2
- FCN2 | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.083); catalogued as COSV99391170; called by muse, mutect2, varscan2
- FKBP10 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387773; called by muse, mutect2, varscan2
- GALNT7 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as rs1282968681, COSV99397113; called by muse, mutect2, varscan2
- GBA | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV100516273; called by muse, mutect2, varscan2
- GCA | c.568+1G>T p.X190_splice | Splice Site (SNP) | VAF 8/85 reads (9%) | catalogued as COSV52025808, COSV99280484; called by muse, mutect2
- GLA | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99516264; called by muse, mutect2, varscan2
- GLMN | c.872A>T p.Y291F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100950001; called by muse, mutect2, varscan2
- GPR155 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99789764; called by muse, mutect2, varscan2
- GRIN3A | c.2189G>C p.R730T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100701418; called by muse, varscan2
- GRIN3A | c.2129G>C p.R710T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701419, COSV62452756; called by muse, varscan2
- GRM5 | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV100550986; called by muse, mutect2, varscan2
- GRM6 | c.962A>C p.D321A | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV99179513; called by muse, mutect2
- GRM7 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100736000; called by muse, mutect2, varscan2
- HCLS1 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as COSV100100477; called by muse, mutect2, varscan2
- HECTD1 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237331; called by muse, mutect2, varscan2
- INTS12 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100415775; called by muse, mutect2
- KCNB1 | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as rs753575587, COSV100870420, COSV100870610; called by muse, mutect2, varscan2
- KCNH8 | c.501T>A p.S167R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100109116; called by muse, mutect2, varscan2
- KIFAP3 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100846825; called by muse, mutect2, varscan2
- LAMP5 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99855504; called by muse, mutect2
- LEFTY1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99686464, COSV99686667; called by muse, mutect2
- LTN1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV63734216; called by muse, mutect2
- MAP4K1 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV101204170; called by muse, mutect2, varscan2
- MCUB | c.528T>A p.H176Q | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101154276; called by muse, mutect2, varscan2
- MDGA2 | c.952G>T p.D318Y (on ENST00000399232 / NM_001113498.2; = p.D20Y on NM_182830.4) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100636639; called by muse, mutect2, varscan2
- MED15 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs773122680, COSV99487489; called by muse, varscan2
- MFSD2B | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV100601015; called by muse, varscan2
- MROH2B | c.2503A>T p.R835W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV101270601; called by muse, mutect2, varscan2
- MTMR9 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99644088; called by muse, mutect2, varscan2
- MYH4 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99700666; called by muse, mutect2, varscan2
- MYH8 | c.4192C>G p.Q1398E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV101238329; called by muse, mutect2, varscan2
- N4BP3 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs769576239, COSV51065160; called by muse, varscan2
- NAV3 | c.3929C>A p.P1310H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57112135, COSV99888519; called by muse, mutect2, varscan2
- NCK2 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99255466; called by muse, mutect2, varscan2
- NEFL | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); catalogued as COSV99647899; called by muse, mutect2, varscan2
- NRG1 | c.1322C>A p.T441K (on ENST00000405005 / NM_013964.5; = p.T446K on NM_013956.5) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs367543167, COSV99828055; called by muse, mutect2, varscan2
- NSUN6 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV101045474; called by muse, mutect2, varscan2
- OR2L2 | c.37T>A p.L13I | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63548806; called by muse, mutect2, varscan2
- OR2L8 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 132/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100594079; called by muse, mutect2, varscan2
- OR2L8 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV100594080; called by muse, mutect2
- OR2T1 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100822275; called by muse, mutect2, varscan2
- OR2T1 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63541790; called by muse, mutect2, varscan2
- OR2T5 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100822172; called by mutect2, varscan2
- OR51G2 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100432080; called by muse, mutect2
- OR5A2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.429); catalogued as COSV100119704, COSV57391250; called by muse, mutect2
- OR8H2 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100542223, COSV57945227, COSV57947119; called by muse, mutect2, varscan2
- OR8H2 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.795); catalogued as COSV57946727; called by muse, mutect2, varscan2
- PASD1 | c.1659G>T p.M553I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.025); catalogued as COSV100949203; called by muse, mutect2
- PCDHB7 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs200672237, COSV50753849; called by muse, mutect2
- PDCD6IP | c.1432A>T p.R478W | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100218627; called by muse, mutect2, varscan2
- PHKG1 | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV51916388, COSV99304994; called by muse, mutect2, varscan2
- PIGK | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV100769821, COSV100769889; called by muse, mutect2, varscan2
- PIGU | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs781506727, COSV99466166; called by muse, mutect2, varscan2
- PIK3CB | c.3023T>A p.L1008* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100005370; called by muse, mutect2, varscan2
- PLAG1 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100387776; called by muse, mutect2, varscan2
- POM121L12 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV101374888, COSV68692878; called by muse, mutect2, varscan2
- PPP2R5D | c.1432C>G p.Q478E | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.832); catalogued as COSV99775636; called by muse, mutect2
- PRSS35 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1157353385, COSV63800795; called by muse, mutect2, varscan2
- PTH1R | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100480878; called by muse, mutect2, varscan2
- RAB18 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803797, COSV100803802; called by muse, mutect2, varscan2
- RBM14 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs959875806, COSV100036607; called by muse, mutect2, varscan2
- RBM4 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs751773381, COSV59520059; called by muse, mutect2, varscan2
- REXO4 | c.562C>G p.P188A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100905720, COSV100905766; called by muse, mutect2, varscan2
- SERPINA9 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100098094; called by muse, mutect2, varscan2
- SEZ6 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV100252800, COSV100253396; called by muse, mutect2
- SIGLEC10 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100218536, COSV100218674; called by muse, mutect2, varscan2
- SLC12A1 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1419661702, COSV66797772; called by muse, mutect2, varscan2
- SMTNL2 | c.770G>T p.G257V (on ENST00000389313 / NM_001114974.2; = p.G113V on NM_198501.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100130624; called by muse, mutect2, varscan2
- SPATC1 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782574956, COSV101084836; called by muse, mutect2, varscan2
- SRGAP3 | c.2499C>A p.N833K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.962); catalogued as COSV100840822; called by muse, mutect2, varscan2
- STXBP1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100964538; called by muse, mutect2, varscan2
- STYXL2 | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV54805247, COSV99608808; called by muse, mutect2, varscan2
- SULT1E1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV56947674, COSV99894812; called by muse, mutect2, varscan2
- TACC1 | c.1183A>G p.N395D | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99393223; called by muse, mutect2, varscan2
- TACC3 | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100508592; called by muse, mutect2, varscan2
- TENM2 | c.4238G>A p.R1413H (on ENST00000518659 / NM_001122679.2; = p.R1174H on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs78965008, COSV69125093; called by muse, mutect2, varscan2
- TIAM1 | c.4543G>T p.V1515L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99733859; called by muse, mutect2, varscan2
- TMTC1 | c.1740G>T p.E580D (on ENST00000539277 / NM_001193451.2; = p.E472D on NM_175861.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99759157; called by muse, mutect2, varscan2
- TUBA3D | c.1196A>C p.Y399S | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100342455; called by muse, mutect2
- TUBB4A | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV99899917; called by muse, mutect2, varscan2
- UBQLN2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1001930696, CM128870, COSV100592663; called by muse, mutect2
- UBR4 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100920630; called by muse, mutect2, varscan2
- VPS18 | c.498A>T p.Q166H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99592381; called by muse, mutect2, varscan2
- VPS18 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99592318, COSV99592383; called by muse, mutect2
- XKR6 | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440422; called by muse, mutect2, varscan2
- ZBTB41 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100962959, COSV100963115; called by muse, mutect2
- ZNF462 | c.7056+1G>T p.X2352_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99471200; called by muse, mutect2, varscan2
- ZNF493 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100828625; called by muse, mutect2, varscan2
- ZNF496 | c.1736G>C p.R579P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV54175748, COSV99665423; called by muse, mutect2, varscan2
- ZNF707 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100690555; called by muse, mutect2, varscan2
- ZSCAN4 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100552430, COSV59001765; called by muse, mutect2, varscan2
- GTF2A1 | c.139del p.E47Kfs*4 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- HTR3D | c.953del p.V318Gfs*63 (on ENST00000382489 / NM_001163646.2; = p.V143Gfs*63 on NM_182537.3) | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- HUWE1 | c.12425+2_12425+6del p.X4142_splice | Splice Site (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 66/776 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2
- MYT1L | c.3167-20_3179del p.X1056_splice | Splice Site (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel
- OR2T12 | c.10A>T p.R4* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | called by mutect2, varscan2
- PCDH11Y | c.3419del p.G1140Afs*43 | Frame Shift Del (DEL) | VAF 33/58 reads (57%) | called by mutect2, pindel, varscan2
- ZMYND8 | c.790del p.Q264Kfs*22 (on ENST00000311275 / NM_001363741.2; = p.Q284Kfs*22 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.1278C>A p.G426= (on ENST00000341937 / NM_001130084.2; = p.G459= on NM_001130083.2) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs41266515, COSV99589269; called by muse, mutect2, varscan2
- AGT | c.129C>T p.L43= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs370335267; called by muse, mutect2, varscan2
- AKAP11 | c.3991C>T p.L1331= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV50292919, COSV50300543; called by muse, mutect2
- AMPH | c.1713C>T p.D571= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1447440426, COSV57743553; called by muse, mutect2
- BCL6B | c.216A>G p.G72= | Silent (SNP) | VAF 44/199 reads (22%) | catalogued as COSV99546508; called by muse, mutect2, varscan2
- BMP2 | c.225G>C p.V75= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV101122065; called by muse, mutect2
- CCDC170 | c.1605C>A p.I535= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99498265; called by muse, mutect2, varscan2
- CCDC185 | c.1518G>A p.L506= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100838769; called by muse, mutect2
- CNTRL | c.5022G>A p.K1674= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs768310513, COSV53049525, COSV99441604; called by muse, mutect2
- DDX23 | c.2079A>G p.T693= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV99974774; called by muse, mutect2, varscan2
- DHX9 | c.1878A>G p.Q626= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as rs755270102, COSV100841313; called by muse, mutect2, varscan2
- DUOX1 | c.3030G>A p.Q1010= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100367751; called by muse, mutect2, varscan2
- DUSP8 | c.63G>T p.R21= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV100524263; called by muse, mutect2, varscan2
- FIGN | c.795G>T p.G265= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs756271439, COSV100291995; called by muse, mutect2, varscan2
- FUT8 | c.495G>T p.T165= (on ENST00000360689 / NM_001371534.1; = p.T2= on NM_004480.4) | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100651220; called by muse, mutect2, varscan2
- GCG | c.108C>G p.S36= | Silent (SNP) | VAF 22/298 reads (7%) | catalogued as COSV64962218; called by muse, mutect2
- GRM5 | c.1224C>G p.A408= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100550985, COSV59600406; called by muse, mutect2, varscan2
- GYS2 | c.1278A>T p.T426= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99679586; called by muse, mutect2, varscan2
- JPH1 | c.1734A>G p.S578= | Silent (SNP) | VAF 12/209 reads (6%) | catalogued as COSV100646490; called by muse, mutect2
- KANK4 | c.2922C>A p.P974= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100443128; called by muse, mutect2, varscan2
- KMT2D | c.2526G>C p.L842= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as COSV99978986; called by muse, mutect2, varscan2
- MSRA | c.90C>T p.I30= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100412627; called by muse, mutect2, varscan2
- MYH13 | c.180C>G p.V60= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99353030; called by muse, mutect2, varscan2
- MYH8 | c.4191C>A p.A1397= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV101238330; called by muse, mutect2, varscan2
- NALCN | c.3447C>A p.T1149= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV99213815; called by muse, mutect2, varscan2
- NPC1L1 | c.3708A>T p.G1236= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99203707; called by muse, mutect2
- NSD2 | c.1935C>T p.D645= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs138013159; called by muse, mutect2, varscan2
- PCDHGA1 | c.2190C>T p.G730= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV65294725; called by muse, mutect2
- PDPK1 | c.213G>A p.P71= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs79145795, COSV99239169; called by muse, mutect2, varscan2
- POLE | c.1674C>T p.C558= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100265800; called by muse, mutect2
- PRKACA | c.459G>C p.L153= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100431937, COSV58069686; called by muse, mutect2
- SLC24A2 | c.1935G>A p.V645= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as COSV99646097; called by muse, mutect2, varscan2
- STMN4 | c.483C>A p.A161= (on ENST00000265770 / NM_001283054.2; = p.A188= on NM_030795.4) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV56108528, COSV99740721; called by muse, mutect2, varscan2
- TACC2 | c.3720C>A p.V1240= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100551888, COSV100554014; called by muse, mutect2, varscan2
- TFPI2 | c.99G>A p.A33= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV55991535; called by muse, mutect2, varscan2
- TSHB | c.204C>A p.S68= | Silent (SNP) | VAF 45/264 reads (17%) | catalogued as COSV99858967; called by muse, mutect2, varscan2
- ZNF488 | c.393C>A p.A131= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ELP4 | c.1147-19910A>G | Intron (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100635224; called by muse, mutect2, varscan2
